Somatic mutation profile of tumor specimen ALCH-B3BV-TTP1-A (aliquot ALCH-B3BV-TTP1-A-1-0-D-A780-36) from ALCHEMIST case ALCH-B3BV, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 66.0 years (24,114 days).
Specimen ALCH-B3BV-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 24191f5c-083b-4962-8055-98c49843c720.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B3BV-NB1-A (Blood Derived Normal), aliquot ALCH-B3BV-NB1-A-1-0-D-A780-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/67aeec84-e1f7-4b98-aa96-d57ea78770c1

The open-access MAF lists 16 somatic variants for this specimen: 9 protein-altering or splice-affecting, 5 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Silent 5, Nonsense Mutation 1, In Frame Del 1, RNA 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.323G>A p.R108K | Missense Mutation (SNP) | VAF 78/265 reads (29%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519828, COSV51766433; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- EGFR | c.2240_2254del p.L747_T751del | In Frame Del (DEL) | VAF 61/338 reads (18%) | hotspot (GDC flag); catalogued as rs121913442, COSV51863059; ClinVar: drug response; called by mutect2, pindel, varscan2
- NFE2L2 | c.70T>C p.W24R | Missense Mutation (SNP) | VAF 6/96 reads (6%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1328994103, COSV67960091, COSV67960815, COSV67963035; called by muse, mutect2
- AKAP6 | c.418G>T p.V140L | Missense Mutation (SNP) | VAF 16/162 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs1204002078; called by muse, mutect2
- RNF146 | c.240G>C p.E80D (on ENST00000368314 / NM_001242850.2; = p.E79D on NM_030963.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/129 reads (8%) | SIFT tolerated (0.4); PolyPhen benign (0.014); catalogued as COSV58931603; called by muse, mutect2
- THAP4 | c.1622G>A p.R541Q | Missense Mutation (SNP) | VAF 7/144 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV58710225; called by muse, mutect2
- CSF2 | c.202G>T p.E68* | Nonsense Mutation (SNP) | VAF 21/172 reads (12%) | called by muse, mutect2, varscan2
- EDARADD | c.52C>T p.H18Y | Missense Mutation (SNP) | VAF 12/127 reads (9%) | SIFT tolerated, low confidence (0.95); PolyPhen benign (0); called by muse, mutect2
- SEPTIN14 | c.526G>T p.D176Y | Missense Mutation (SNP) | VAF 47/117 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DUSP22 | c.405C>T p.L135= | Silent (SNP) | VAF 14/130 reads (11%) | catalogued as COSV60527126; called by muse, mutect2, varscan2
- LAG3 | c.1560C>G p.P520= | Silent (SNP) | VAF 5/52 reads (10%) | catalogued as rs1428714933; called by muse, mutect2
- MXRA5 | c.4593G>A p.L1531= | Silent (SNP) | VAF 36/180 reads (20%) | catalogued as rs748730482; called by muse, mutect2, varscan2
- PKLR | c.324C>A p.I108= | Silent (SNP) | VAF 20/186 reads (11%) | called by muse, mutect2, varscan2
- RLIM | c.1617G>A p.E539= | Silent (SNP) | VAF 20/244 reads (8%) | called by muse, mutect2
- AOC4P | n.1322G>A | RNA (SNP) | VAF 9/83 reads (11%) | catalogued as rs561283126; called by muse, mutect2, varscan2
- CCDC40 | c.1807-34C>T | Intron (SNP) | VAF 9/90 reads (10%) | called by muse, mutect2, varscan2
